Gene-level copy-number profile of tumor specimen C3N-02920-03 from CPTAC case C3N-02920, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 48.9 years (17,859 days).
Specimen C3N-02920-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9c91dcb5-4af2-4ee5-af76-443477340c3a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02920-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/916ba395-190e-4432-bdcc-0a9b6d89dc11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 127; copy number 2: 57,132; copy number 3: 808; copy number 4: 109; copy number 5: 97; copy number 6: 100; copy number 7: 19; copy number 8: 1; copy number 9: 4; copy number 10: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 227 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–612,210, 24 genes, copy number 6–8: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1.
- chr5:850,291–892,801, 1 gene, copy number 5 (within-gene range 3–5): BRD9.
- chr5:1,544,107–4,874,759, 45 genes, copy number 5–10: AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1.
- chr5:8,207,019–8,794,197, 21 genes, copy number 5: AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3.
- chr5:10,225,507–10,777,062, 30 genes, copy number 5: ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr5:171,773,652–173,292,619, 39 genes, copy number 6: AC011410.1, SMIM23, FBXW11, STK10, EFCAB9, UBTD2, AC024561.1, KLF3P1, SH3PXD2B, LINC01944, AC027309.3, NEURL1B, AC027309.2, MIR5003, AC027309.1, AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4, AC110011.1, ERGIC1, AC008429.1, AC008429.3, RPL26L1, AC008429.2, ATP6V0E1, AC008429.4, SNORA74B, Y_RNA, CREBRF, CDC42P5, AC008378.1, BNIP1, RPL7AP33, NKX2-5, Y_RNA, RNA5SP200.
- chr5:174,045,706–174,633,209, 10 genes, copy number 5: NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3.
- chr8:30,095,408–30,177,208, 1 gene, copy number 7 (within-gene range 2–7): LEPROTL1.
- chr8:30,131,671–30,353,518, 11 genes, copy number 7: MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC109329.1, PPIAP84, TUBBP1.
- chr12:68,473,741–68,687,755, 10 genes, copy number 5 (within-gene range 2–5): AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42.
- chr12:71,709,171–71,800,286, 3 genes, copy number 6: AC011601.1, RAB21, AC089984.1.
- chr13:110,305,812–110,513,209, 1 gene, copy number 6 (within-gene range 2–6): COL4A2.
- chr13:110,456,396–110,561,722, 3 genes, copy number 6: COL4A2-AS2, COL4A2-AS1, RAB20.
- chr13:113,491,021–114,337,626, 25 genes, copy number 6–10: TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr19:46,719,511–46,746,994, 3 genes, copy number 5 (within-gene range 2–5): STRN4, AC008635.1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 127. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
